Gene-level copy-number profile of tumor specimen MP2PRT-PANVJI-TMP1-A from MP2PRT case MP2PRT-PANVJI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,257 days).
Specimen MP2PRT-PANVJI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file efb32d37-5df5-40da-923e-0a113ca9f9ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PANVJI-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/d31b19a6-a055-4b84-8de6-fc08f08b1a3e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 176; copy number 1: 142; copy number 2: 58,041; copy number 3: 27.

Homozygous deletions (total copy number 0; autosomes only): 176 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,825,207, 2 genes (within-gene range 0–2): MALLP2, MIR4436A.
- chr2:89,159,751–89,196,829, 6 genes (within-gene range 0–1): IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26.
- chr14:22,449,113–22,459,156, 5 genes (within-gene range 0–3): TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:22,483,004–22,511,024, 23 genes (within-gene range 0–3): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31.
- chr14:105,672,308–106,538,344, 132 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,564,375–106,566,555, 2 genes (within-gene range 0–1): IGHVII-49-1, IGHV3-50.
- chr22:22,198,560–22,245,515, 6 genes: IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 142. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
